Surgical pathology report (de-identified scan), TCGA case TCGA-27-1830, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Milan - Italy, Fondazione IRCCS Instituto Neuroligico C. Besta, specimen TCGA-27-1830-01A (Primary Tumor).

Ref. Number

Gender

Birth date

Tumor site

Right temporal

Histological diagnosis

Glioblastoma multiforme

Note: for only

Source: NCI Genomic Data Commons file fe99177b-ae45-4d00-b1ab-d5ad025880ba (TCGA-27-1830.19FB9F5C-3E84-471E-84A3-DAAE18D97D71.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).